Somatic mutation profile of tumor specimen TCGA-CV-7102-01A (aliquot TCGA-CV-7102-01A-11D-2012-08) from TCGA case TCGA-CV-7102, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 76.1 years (27,805 days).
Specimen TCGA-CV-7102-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d044506-bd60-4055-a3fa-1beee3c5aa72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7102-10A (Blood Derived Normal), aliquot TCGA-CV-7102-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6407f8d8-2ee9-45d4-9aec-3f7c8849a02a

The open-access MAF lists 155 somatic variants for this specimen: 116 protein-altering or splice-affecting, 33 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 33, Nonsense Mutation 9, Splice Site 3, Intron 2, Frame Shift Ins 2, 3'Flank 2, RNA 1, Splice Region 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHOA | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 25/134 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs1057519951, COSV69041613, COSV69042111, COSV69043712; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 8/19 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: pathogenic / likely pathogenic / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2
- ABHD5 | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV50007070, COSV99185486; called by muse, mutect2, varscan2
- ABLIM2 | c.1311C>G p.I437M (on ENST00000341937 / NM_001130084.2; = p.I470M on NM_001130083.2) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99589899; called by muse, mutect2, varscan2
- ABRA | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.085); catalogued as COSV100357607; called by muse, mutect2, varscan2
- ADAM29 | c.1068G>A p.M356I | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100822073; called by muse, mutect2, varscan2
- ADD1 | c.90G>C p.E30D | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.411); catalogued as COSV99296646; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1570C>G p.L524V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99783728; called by muse, mutect2, varscan2
- AOPEP | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV99468786; called by muse, mutect2, varscan2
- ARIH1 | c.1248C>G p.F416L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as COSV101158761; called by muse, mutect2, varscan2
- ARMC8 | c.1769A>G p.K590R (on ENST00000469044 / NM_001363941.2; = p.K576R on NM_015396.6) | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.899); catalogued as COSV100509746; called by muse, mutect2, varscan2
- ASGR1 | c.537C>A p.D179E | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99352558; called by muse, mutect2, varscan2
- ASPM | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV54126964; called by muse, mutect2, varscan2
- AURKB | c.732G>A p.M244I | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.234); catalogued as COSV60246427; called by muse, mutect2, varscan2
- BCLAF3 | c.653C>G p.S218* | Nonsense Mutation (SNP) | VAF 24/133 reads (18%) | catalogued as COSV100503338; called by muse, mutect2, varscan2
- BLVRA | c.586G>C p.D196H | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as COSV99646040; called by muse, mutect2, varscan2
- C2orf16 | c.3635C>T p.T1212I | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.323); catalogued as COSV100820856; called by muse, mutect2, varscan2
- C8A | c.1571T>G p.L524W | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.502); catalogued as COSV100776562; called by muse, varscan2
- CALCOCO1 | c.609+1G>A p.X203_splice | Splice Site (SNP) | VAF 8/79 reads (10%) | catalogued as COSV100017386; called by muse, mutect2, varscan2
- CALCOCO1 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); catalogued as COSV100017388, COSV50414563; called by muse, mutect2, varscan2
- CCDC110 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs376940059; called by muse, mutect2, varscan2
- CD99L2 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 36/259 reads (14%) | catalogued as rs781914244, COSV100692331, COSV60937705; called by muse, mutect2, varscan2
- CDH13 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1477620126, COSV99227440; called by muse, mutect2, varscan2
- CDKN1B | c.86G>T p.C29F | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99963989; called by muse, mutect2, varscan2
- CEP112 | c.2358G>C p.K786N | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV101210842; called by muse, mutect2, varscan2
- CLK2 | c.938G>A p.R313Q (on ENST00000368361 / NM_001294339.2; = p.R312Q on NM_003993.4) | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.196); catalogued as rs779179029, COSV100226789, COSV56946407; called by muse, mutect2, varscan2
- CTCF | c.1429C>T p.H477Y | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV50465416; called by muse, mutect2, varscan2
- DCAF4 | c.352-1G>C p.X118_splice | Splice Site (SNP) | VAF 42/122 reads (34%) | catalogued as COSV62319652; called by muse, mutect2, varscan2
- DDX41 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 42/264 reads (16%) | catalogued as COSV100286661; called by muse, mutect2, varscan2
- DES | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | catalogued as rs61726467, CM071702, CX094917, COSV100900470; called by muse, mutect2, varscan2
- DNAH10 | c.12174G>A p.M4058I (on ENST00000409039; = p.M3997I on NM_207437.3) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs796742287, COSV101292353; called by mutect2, varscan2
- DPP4 | c.295G>C p.G99R | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.2); catalogued as COSV100858930; called by muse, mutect2, varscan2
- DTNA | c.1900G>C p.E634Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as COSV52008898, COSV99313523; called by muse, mutect2, varscan2
- DUOX1 | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772380394, COSV100368123; called by muse, mutect2, varscan2
- DUSP3 | c.458T>C p.I153T | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99871499; called by muse, mutect2, varscan2
- EBF1 | c.263C>A p.A88E | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV100566024; called by muse, mutect2, varscan2
- EHMT2 | c.782A>G p.E261G | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.109); catalogued as COSV100977223; called by muse, mutect2, varscan2
- EIF4G3 | c.3076G>T p.G1026C | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99944784; called by muse, mutect2, varscan2
- ELF3 | c.167A>G p.K56R | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.963); catalogued as COSV100668863; called by muse, mutect2, varscan2
- ENOX2 | c.1067G>A p.R356Q (on ENST00000338144 / NM_001382520.1; = p.R327Q on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV57656332; called by muse, mutect2, varscan2
- ETV3L | c.1045C>G p.L349V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV101485600; called by muse, mutect2
- EVA1C | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs780846738, COSV100291428; called by muse, mutect2, varscan2
- FAM3A | c.169T>A p.Y57N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as COSV100453664; called by muse, mutect2, varscan2
- FIG4 | c.2222C>T p.T741M | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs1274229885, COSV57791213; ClinVar: uncertain significance; called by muse, mutect2
- FOXD4L1 | c.221T>A p.I74N | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs761984151, COSV99380630; called by muse, mutect2, varscan2
- GABRG2 | c.889G>T p.G297* (on ENST00000361925 / NM_001375343.1; = p.G257* on NM_000816.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as CM155068, COSV100729751, COSV62721042; called by muse, mutect2, varscan2
- GBP7 | c.681C>A p.F227L | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as COSV99643221; called by muse, mutect2, varscan2
- GFM1 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as COSV99962971; called by muse, mutect2, varscan2
- GOSR1 | c.300G>C p.L100F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.058); catalogued as COSV56718926; called by muse, mutect2, varscan2
- GYS2 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs373682083; called by muse, mutect2, varscan2
- HDAC8 | c.970G>C p.G324R | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.85); catalogued as COSV101005269, COSV101005328; called by muse, mutect2, varscan2
- HERC1 | c.6179A>G p.Y2060C | Missense Mutation (SNP) | VAF 88/252 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101496661; called by muse, mutect2, varscan2
- HIF3A | c.239C>G p.A80G (on ENST00000377670 / NM_152795.4; = p.A78G on NM_152794.4) | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99355902; called by muse, varscan2
- HIP1 | c.2884G>T p.E962* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as COSV61187873; called by muse, mutect2, varscan2
- HOXA1 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.575); catalogued as COSV58030611; called by muse, varscan2
- HSPA4L | c.2418C>G p.H806Q | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99613211; called by muse, mutect2, varscan2
- INTS14 | c.781G>A p.D261N (on ENST00000313182 / NM_001366360.2; = p.D182N on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100500002; called by muse, mutect2
- ITPRIPL1 | c.699G>C p.Q233H (on ENST00000439118 / NM_001008949.3; = p.Q241H on NM_178495.6) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100742206; called by muse, mutect2, varscan2
- KALRN | c.3330G>T p.Q1110H | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99565391; called by muse, mutect2, varscan2
- KCNV1 | c.175T>A p.C59S | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99819203; called by muse, mutect2
- KCTD8 | c.1144C>T p.H382Y | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.173); catalogued as COSV100759718; called by muse, mutect2, varscan2
- KIAA0319L | c.1808C>G p.A603G | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100357473, COSV57847268; called by muse, mutect2, varscan2
- KIAA0319L | c.1807G>C p.A603P | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100357475; called by muse, mutect2, varscan2
- KIAA1210 | c.4396C>A p.L1466I | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.134); catalogued as COSV101274272; called by mutect2, varscan2
- KIAA1549L | c.4537G>A p.E1513K (on ENST00000321505; = p.E1810K on NM_012194.3) | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1318621265, COSV100381814; called by muse, mutect2, varscan2
- KLHL26 | c.582G>C p.Q194H | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.726); catalogued as COSV99963241; called by muse, mutect2, varscan2
- KRT23 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV99266265, COSV99266278; called by muse, mutect2, varscan2
- LENG8 | c.1737G>C p.L579F | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100418113; called by muse, mutect2, varscan2
- LRBA | c.6802G>A p.D2268N | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100841813; called by muse, mutect2, varscan2
- LRPPRC | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs201021305, COSV99580472; called by muse, mutect2, varscan2
- LRRC37A2 | c.3718G>C p.E1240Q | Missense Mutation (SNP) | VAF 20/271 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs1287620590, COSV100238778; called by muse, mutect2
- LRRC8E | c.1405C>T p.H469Y | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100143017; called by muse, mutect2, varscan2
- MED12 | c.2982-1G>T p.X994_splice | Splice Site (SNP) | VAF 12/37 reads (32%) | catalogued as COSV61340577, COSV61359161; called by muse, mutect2, varscan2
- MMRN1 | c.2888T>C p.L963P | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as COSV53341011; called by muse, mutect2, varscan2
- MRPS7 | c.79C>G p.P27A | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs778523905, COSV99821648; called by muse, mutect2, varscan2
- MSR1 | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs774483136, COSV100027531; called by muse, mutect2, varscan2
- MTRR | c.1003C>T p.Q335* (on ENST00000264668; = p.Q308* on NM_002454.3 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/106 reads (9%) | catalogued as COSV99241850; called by muse, mutect2, varscan2
- MYO9A | c.2254C>T p.H752Y | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as COSV100613838; called by muse, mutect2, varscan2
- NEDD4 | c.1130C>T p.S377L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated, low confidence (0.79); PolyPhen possibly damaging (0.459); catalogued as COSV100163859; called by muse, mutect2, varscan2
- NFIC | c.1086G>T p.G362= | Splice Region (SNP) | VAF 56/257 reads (22%) | catalogued as COSV100545481; called by muse, mutect2, varscan2
- OTUB2 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as rs373645481, COSV99180189; called by muse, mutect2, varscan2
- PALLD | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs535947672, COSV54974843, COSV54996218; called by muse, mutect2, varscan2
- PCDHB11 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.225); catalogued as rs782300907, COSV100697055; called by muse, mutect2, varscan2
- PCDHB12 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV99507465; called by muse, mutect2, varscan2
- PCDHB12 | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.521); catalogued as rs782400979, COSV53399192; called by muse, mutect2, varscan2
- PHF3 | c.5759G>A p.R1920H | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs755576463, COSV100012840; called by muse, mutect2, varscan2
- PKM | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1473418252, COSV100064931; called by muse, mutect2, varscan2
- PLCXD2 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.986); catalogued as COSV101210102; called by muse, mutect2, varscan2
- PSMB8 | c.820G>T p.A274S (on ENST00000374882 / NM_148919.4; = p.A270S on NM_004159.5) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as COSV100841239; called by muse, varscan2
- PTPN7 | c.788C>T p.S263L (on ENST00000495688; = p.S302L on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV100459946; called by muse, mutect2, varscan2
- RAI2 | c.583C>A p.Q195K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.616); catalogued as COSV100518410; called by muse, varscan2
- RBP2 | c.320G>A p.W107* | Nonsense Mutation (SNP) | VAF 34/211 reads (16%) | catalogued as COSV99218408; called by muse, mutect2, varscan2
- SBDS | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.301); catalogued as COSV99886090; called by muse, mutect2, varscan2
- SEL1L2 | c.1790T>A p.M597K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99533447; called by muse, mutect2, varscan2
- SLC2A1 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV65287442; called by muse, mutect2, varscan2
- SLC4A2 | c.3349G>T p.V1117L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99879618, COSV99879835; called by muse, mutect2, varscan2
- SLIT2 | c.1972A>G p.T658A | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV99884970; called by muse, mutect2, varscan2
- SORBS2 | c.1554G>C p.Q518H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV99511540, COSV99512499; called by muse, mutect2, varscan2
- SPACA7 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs201127697; called by muse, mutect2, varscan2
- TRHDE | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.903); catalogued as COSV53870606; called by muse, mutect2, varscan2
- TSC2 | c.1954G>C p.E652Q | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV99554604; called by muse, mutect2
- TTN | c.81433G>C p.V27145L (on ENST00000591111; = p.V19721L on NM_003319.4) | Missense Mutation (SNP) | VAF 38/137 reads (28%) | PolyPhen benign (0.269); catalogued as COSV100618980; called by muse, mutect2, varscan2
- UGT2A1 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0.011); catalogued as COSV99684559; called by muse, mutect2, varscan2
- UNC13A | c.3985A>G p.T1329A | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV99408745; called by muse, mutect2, varscan2
- UNC13B | c.2113G>A p.V705I | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs138199360; called by muse, mutect2, varscan2
- VPS13D | c.11264T>G p.L3755W | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV99167357; called by muse, mutect2, varscan2
- XKRX | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 71/261 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100139715; called by muse, mutect2, varscan2
- XPO1 | c.2599C>T p.P867S | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.097); catalogued as rs190205938, COSV68947975; called by muse, mutect2, varscan2
- ZFP2 | c.538C>A p.H180N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100797073; called by muse, mutect2, varscan2
- ZNF264 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV99567302; called by muse, mutect2, varscan2
- ZNF430 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as COSV99841844; called by muse, mutect2, varscan2
- MAGEA3 | c.821del p.G274Vfs*11 | Frame Shift Del (DEL) | VAF 32/275 reads (12%) | called by mutect2, pindel, varscan2
- PIP4K2B | c.959A>T p.Y320F | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SYDE2 | c.874dup p.Y292Lfs*9 | Frame Shift Ins (INS) | VAF 49/180 reads (27%) | called by mutect2, pindel, varscan2
- TANC1 | c.4145dup p.N1382Kfs*2 | Frame Shift Ins (INS) | VAF 37/138 reads (27%) | called by mutect2, pindel, varscan2
- TRGC1 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 46/216 reads (21%) | called by muse, varscan2
- ABTB1 | c.603C>T p.L201= (on ENST00000232744 / NM_172027.3; = p.L59= on NM_032548.3) | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs774955172, COSV99229924; called by muse, mutect2, varscan2
- ADGRG4 | c.6030C>G p.L2010= | Silent (SNP) | VAF 19/167 reads (11%) | catalogued as COSV99795923; called by muse, mutect2, varscan2
- ALPK1 | c.2865G>C p.G955= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs1350686930, COSV99454455; called by muse, mutect2, varscan2
- CDC42BPG | c.1014A>G p.E338= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as COSV100712110; called by muse, mutect2, varscan2
- CIT | c.3018C>T p.T1006= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV99950097; called by muse, mutect2, varscan2
- CNTN1 | c.2724T>A p.P908= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100751574; called by muse, mutect2, varscan2
- CSDC2 | c.255C>T p.I85= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV99348180; called by muse, mutect2, varscan2
- CUBN | c.9396C>T p.F3132= | Silent (SNP) | VAF 40/197 reads (20%) | catalogued as COSV100912994; called by muse, mutect2, varscan2
- DMD | c.6885C>G p.L2295= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as COSV100628031; called by muse, mutect2, varscan2
- EGFR | c.1776C>T p.V592= | Silent (SNP) | VAF 24/704 reads (3%) | catalogued as COSV51852132; called by muse, mutect2
- FBXO31 | c.1473C>T p.F491= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs141426651; called by muse, mutect2, varscan2
- GABRB2 | c.132G>C p.L44= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV99196251, COSV99196530; called by muse, mutect2, varscan2
- GIPC3 | c.441G>A p.R147= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100461383; called by muse, mutect2, varscan2
- HTR3E | c.1287C>T p.H429= (on ENST00000415389 / NM_001256613.1; = p.H444= on NM_182589.2) | Silent (SNP) | VAF 23/126 reads (18%) | catalogued as COSV100094267; called by muse, mutect2, varscan2
- KLHL22 | c.1446G>A p.R482= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as COSV100186116; called by muse, mutect2, varscan2
- LIPG | c.909C>T p.F303= | Silent (SNP) | VAF 18/138 reads (13%) | catalogued as COSV99724540; called by muse, mutect2, varscan2
- MAGEH1 | c.429A>G p.R143= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV100746823; called by muse, mutect2, varscan2
- MNDA | c.993C>T p.S331= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs993369232, COSV63740362; called by muse, mutect2, varscan2
- MPP1 | c.15G>A p.A5= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV101053712; called by muse, mutect2
- OMP | c.105C>T p.R35= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs368926826; called by muse, mutect2, varscan2
- OR13H1 | c.567T>G p.S189= | Silent (SNP) | VAF 53/311 reads (17%) | catalogued as COSV100088324; called by muse, mutect2, varscan2
- RAI2 | c.582C>A p.S194= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100518413; called by muse, varscan2
- RASGRP2 | c.252C>T p.S84= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs775834035, COSV100818289; called by muse, mutect2, varscan2
- SEMA6B | c.840G>A p.K280= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV100014939; called by muse, mutect2, varscan2
- SLC26A3 | c.2112G>A p.V704= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100385161; called by muse, mutect2, varscan2
- SLC31A1 | c.387C>T p.S129= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as COSV100951928; called by muse, varscan2
- SLCO1B3 | c.1317C>T p.T439= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs1424838811, COSV99681678; called by muse, mutect2, varscan2
- TFCP2L1 | c.195G>A p.T65= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs764238186, COSV55290594; called by mutect2, varscan2
- TRAF7 | c.195C>T p.T65= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs777048598, COSV100399638; called by muse, mutect2, varscan2
- UBE2NL | c.81A>G p.P27= | Silent (SNP) | VAF 48/163 reads (29%) | called by muse, mutect2, varscan2
- WDR7 | c.798C>G p.V266= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as COSV99589721; called by muse, mutect2, varscan2
- ZNF101 | c.1002A>T p.G334= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100543578; called by muse, mutect2, varscan2
- ZNF418 | c.1317C>A p.G439= | Silent (SNP) | VAF 42/195 reads (22%) | catalogued as COSV101268951; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824207 G>C | 5'Flank (SNP) | VAF 3/8 reads (38%) | called by muse, mutect2
- AL353804.7 | chrX:73852038 C>T | 3'Flank (SNP) | VAF 9/34 reads (26%) | catalogued as rs1410807624; called by muse, mutect2
- DYRK1A | c.1671+51G>C | Intron (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100117876, COSV100118009; called by muse, mutect2, varscan2
- RPS8 | c.387+88G>T | Intron (SNP) | VAF 10/85 reads (12%) | catalogued as COSV100785480; called by muse, mutect2, varscan2
- SNORD115-23 | n.44G>A | RNA (SNP) | VAF 39/275 reads (14%) | called by muse, mutect2, varscan2
- TAOK2 | chr16:29990811 G>A | 3'Flank (SNP) | VAF 12/71 reads (17%) | catalogued as COSV99663146; called by muse, mutect2, varscan2
